Somatic mutation profile of tumor specimen TARGET-10-PANXSF-09A (aliquot TARGET-10-PANXSF-09A-01D) from TARGET case TARGET-10-PANXSF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (754 days).
Specimen TARGET-10-PANXSF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cdc29d5-4060-4f64-bae5-4c3163467b39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXSF-14A (Bone Marrow Normal), aliquot TARGET-10-PANXSF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5465ede2-78f3-4d33-941d-186e2048029d

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, Intron 1, Silent 1, 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MIGA1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 13/166 reads (8%) | catalogued as rs754213248, COSV66223214; called by muse, mutect2
- RAI1 | c.5682C>A p.N1894K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- ZP1 | c.456C>A p.A152= | Silent (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- DST | c.14503+77A>G | Intron (SNP) | VAF 4/54 reads (7%) | catalogued as rs1278852156; called by muse, mutect2
- RFX7 | c.*5769A>C | 3'UTR (SNP) | VAF 6/92 reads (7%) | catalogued as rs941871440; called by muse, mutect2
